Surgical pathology report (de-identified scan), TCGA case TCGA-06-0402, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0402-01A (Primary Tumor).

Patient Name:

MRN:

Birth Date:

Sex: Male Room/Bed:

PATIENT NAME:

H.P. NO.

AGE/SEX: M

ORDERING PHYSICIAN:

NAME:

AGE/SEX: M

PHYSICIAN

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN BIOPSY: GLIOBLASTOMA MULTIFORME.
B. DURA: INVOLVED BY GLIOBLASTOMA.
-

Operation/Specimen: 2)Dura. 3)Tumor.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY: A. Labeled "brain biopsy", are several 10.2 to 0.4 cm. pink-white tissue. Portion of the specimen has been examined by frozen section and submitted in cassette 1; remaining tissue in cassette 2.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Astrocytoma.

B. Labeled "dura", is a portion of cerebral dura, 4.2 x 3.8 cm. There are several 0.3 to 0.4 cm. gray-white nodules on the inner surface of the dura. Representative sections submitted in cassette 3.

C. Labeled "tumor", are multiple 0.5 to 2.8 cm. irregular pink-white to dark brown tissue aggregating 4 x 4 x 1 cm. Portion of the specimen is submitted in cassettes 4-8.

MICROSCOPIC: Sections show a glioblastoma multiforme with involvement of the overlying cerebral dura. The tumor is characterized by hypercellular density marked vascular proliferation with frequent thrombosis and large areas of necrosis. There tumor appears to originate as an oligodendroglioma which can be identified in most sections. The oligodendroglioma portion is largely negative for GFAP that is in contrast to the GFAP positive glioblastoma portion.

SPECIAL STAINS: GFAP and reticulum.

BILLING CODES:

Source: NCI Genomic Data Commons file 49018fc9-bde9-4847-8e0b-f0f30802b3b5 (TCGA-06-0402.748385B4-091D-44BD-97DF-717AD70405EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).